Somatic mutation profile of tumor specimen CDDP-ABIX-TTP2-A (aliquot CDDP-ABIX-TTP2-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABIX, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60 years.
Specimen CDDP-ABIX-TTP2-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1bcf612-2267-4251-8e2f-fab64f10daf5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABIX-NB1-A (Blood Derived Normal), aliquot CDDP-ABIX-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bcabc86-fe33-4041-aa92-f567a476a1a9

The open-access MAF lists 442 somatic variants for this specimen: 304 protein-altering or splice-affecting, 93 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 257, Silent 93, Intron 20, Nonsense Mutation 19, Frame Shift Del 12, RNA 9, 5'UTR 7, Splice Site 7, Frame Shift Ins 5, 3'UTR 4, 5'Flank 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.6118-1G>A p.X2040_splice | Splice Site (SNP) | VAF 26/186 reads (14%) | catalogued as rs1060502656, CS111775; ClinVar: pathogenic; called by muse, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 279/535 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 139/189 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, mutect2, varscan2
- ACAD8 | c.109+1G>A p.X37_splice | Splice Site (SNP) | VAF 235/446 reads (53%) | catalogued as rs745741186; called by muse, mutect2, varscan2
- ACTL6B | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 101/184 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as rs1431929583, COSV99355685; called by muse, mutect2, varscan2
- ANKK1 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.492); catalogued as rs770430581; called by muse, mutect2, varscan2
- ANO1 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 131/288 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs755991298; called by muse, mutect2, varscan2
- BDP1 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.792); catalogued as COSV62430772, COSV62435640; called by muse, mutect2, varscan2
- C7orf31 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 46/282 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV52218824; called by muse, mutect2, varscan2
- CACNG7 | c.632G>C p.R211P | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV55813999, COSV55817957; called by muse, mutect2, varscan2
- CASP8AP2 | c.3274G>A p.V1092M | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs1470513736; called by muse, mutect2, varscan2
- CD22 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs1044841386; called by muse, mutect2, varscan2
- CDH10 | c.1667G>A p.R556K | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs1452893105; called by muse, mutect2, varscan2
- CEP164 | c.4376G>A p.R1459H | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99634494; called by muse, mutect2, varscan2
- CFH | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as COSV66406370; called by muse, mutect2, varscan2
- CLCA4 | c.795A>G p.I265M | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs965913722, COSV55367333; called by muse, mutect2
- CLCN5 | c.1687C>A p.R563S | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV100260258; called by muse, mutect2, varscan2
- CLSTN2 | c.2708G>T p.G903V | Missense Mutation (SNP) | VAF 148/441 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV101515830; called by muse, mutect2, varscan2
- CNTN5 | c.633G>T p.Q211H | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs142016741; called by muse, mutect2, varscan2
- COL15A1 | c.2308G>C p.G770R | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100897296; called by muse, mutect2, varscan2
- COL5A1 | c.3148G>A p.D1050N | Missense Mutation (SNP) | VAF 44/324 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); catalogued as COSV100880597; called by muse, mutect2, varscan2
- DCHS1 | c.8663G>T p.G2888V | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV54997748; called by muse, mutect2, varscan2
- DDHD2 | c.1778C>T p.S593L | Missense Mutation (SNP) | VAF 119/207 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs371592123; called by muse, mutect2, varscan2
- DMP1 | c.1504G>T p.G502W | Missense Mutation (SNP) | VAF 310/593 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV99218851; called by muse, mutect2, varscan2
- DNAH1 | c.8412del p.K2805Rfs*21 | Frame Shift Del (DEL) | VAF 32/155 reads (21%) | catalogued as COSV101325214; called by mutect2, pindel, varscan2
- DPYD | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); catalogued as COSV64605231; called by muse, mutect2, varscan2
- EDC4 | c.3044G>T p.R1015L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs747711628; called by muse, mutect2, varscan2
- FAM47A | c.1526C>A p.P509H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV60499012; called by muse, varscan2
- FBN2 | c.5225G>T p.R1742L | Missense Mutation (SNP) | VAF 112/218 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs774411234, COSV52556315; called by muse, mutect2, varscan2
- FRYL | c.1816G>T p.D606Y | Missense Mutation (SNP) | VAF 110/378 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51947084, COSV51950581, COSV51955022; called by muse, mutect2, varscan2
- FSIP2 | c.13999G>A p.G4667R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1356150479; called by muse, mutect2, varscan2
- GFRA1 | c.267C>A p.C89* | Nonsense Mutation (SNP) | VAF 143/207 reads (69%) | catalogued as COSV62608723; called by muse, mutect2, varscan2
- GRM8 | c.105G>T p.E35D | Missense Mutation (SNP) | VAF 128/286 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV100285200; called by muse, mutect2, varscan2
- HBB | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 309/579 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as CM870035, COSV99062335; called by muse, mutect2, varscan2
- HEYL | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs576981180, COSV100865274; called by muse, mutect2, varscan2
- HNRNPDL | c.176G>C p.R59P | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs1052197802, COSV55022400; called by muse, mutect2, varscan2
- HRNR | c.8425G>T p.G2809W | Missense Mutation (SNP) | VAF 191/493 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.87); catalogued as rs756387923; called by muse, mutect2, varscan2
- HYDIN | c.9137C>T p.T3046I | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.074); catalogued as rs1309414303; called by muse, mutect2, varscan2
- ILF3 | c.2678A>G p.Y893C | Missense Mutation (SNP) | VAF 48/65 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs781616776; called by muse, mutect2, varscan2
- IMPA2 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs754589142, COSV52320717, COSV99302712; called by muse, mutect2, varscan2
- INO80 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs202070069, COSV62741065; called by muse, mutect2, varscan2
- KCNH1 | c.2215C>T p.R739C (on ENST00000271751 / NM_172362.3; = p.R712C on NM_002238.4) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs767728728, COSV55090783; called by muse, mutect2, varscan2
- KCNU1 | c.2707G>C p.G903R | Missense Mutation (SNP) | VAF 64/112 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as COSV101299146, COSV67759715; called by muse, mutect2, varscan2
- KIAA1614 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 81/316 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs757603689, COSV62553656; called by muse, mutect2, varscan2
- KIDINS220 | c.4510C>A p.Q1504K | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.137); catalogued as COSV56760277; called by muse, mutect2, varscan2
- KNDC1 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 209/311 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1013580271; called by muse, varscan2
- KRT37 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 118/501 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); catalogued as COSV56658554, COSV99845625; called by muse, mutect2, varscan2
- LCE1B | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 88/333 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100780316; called by muse, mutect2, varscan2
- LCT | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 228/617 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV99919411; called by muse, mutect2, varscan2
- LILRB2 | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 208/424 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs202182093; called by muse, mutect2, varscan2
- MED14 | c.1060G>T p.V354F | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV100247409; called by muse, mutect2, varscan2
- MESP2 | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV59092578; called by muse, mutect2, varscan2
- MOSPD1 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV100887863; called by muse, mutect2, varscan2
- MXRA5 | c.6015C>A p.H2005Q | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV54235580; called by muse, mutect2, varscan2
- MYH7B | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs748644297; called by muse, mutect2, varscan2
- NAV3 | c.944C>A p.A315D | Missense Mutation (SNP) | VAF 118/209 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs769963958; called by muse, mutect2, varscan2
- NBEA | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 76/142 reads (54%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.098); catalogued as COSV59809816; called by muse, mutect2, varscan2
- NFKBIA | c.337-1G>C p.X113_splice | Splice Site (SNP) | VAF 72/346 reads (21%) | catalogued as COSV53752571, COSV53752821; called by muse, mutect2, varscan2
- NTN1 | c.883G>T p.V295L | Missense Mutation (SNP) | VAF 97/157 reads (62%) | SIFT tolerated (0.56); PolyPhen benign (0.055); catalogued as rs577333476, COSV99432409; called by muse, mutect2, varscan2
- OCA2 | c.1596del p.W532* | Frame Shift Del (DEL) | VAF 67/352 reads (19%) | catalogued as COSV100668502; called by mutect2, pindel, varscan2
- OR10T2 | c.670A>G p.N224D | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV100555125; called by muse, mutect2, varscan2
- OR4A5 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 47/96 reads (49%) | catalogued as COSV60524301; called by muse, mutect2
- PABPC1L | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 156/467 reads (33%) | catalogued as COSV53842156; called by muse, mutect2, varscan2
- PASD1 | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs762183231, COSV64857376; called by muse, mutect2
- PCDHB6 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV50695454, COSV99170084; called by muse, mutect2, varscan2
- PLCG2 | c.2239A>G p.R747G | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.995); catalogued as rs774085526; called by muse, mutect2
- PLD4 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66915391; called by muse, mutect2, varscan2
- PNLIPRP3 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100982647; called by muse, mutect2, varscan2
- POU2F3 | c.362-4C>A | Splice Region (SNP) | VAF 23/110 reads (21%) | catalogued as COSV52793278; called by muse, mutect2, varscan2
- POU4F1 | c.1201del p.V401Cfs*13 | Frame Shift Del (DEL) | VAF 57/305 reads (19%) | catalogued as COSV65884565; called by mutect2, pindel, varscan2
- PRDM9 | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 49/403 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV57002771, COSV57005738; called by muse, mutect2, varscan2
- PROM2 | c.1218G>T p.E406D | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV58300044; called by muse, mutect2, varscan2
- PRX | c.1802C>G p.P601R | Missense Mutation (SNP) | VAF 126/731 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778475989; called by muse, mutect2, varscan2
- PYGM | c.2053A>T p.N685Y | Missense Mutation (SNP) | VAF 121/567 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM991089; called by muse, mutect2, varscan2
- RASL12 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs750947249, COSV54981365; called by muse, mutect2, varscan2
- RETREG1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs759050645; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RSPH6A | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as rs148871208; called by muse, mutect2, varscan2
- SHANK1 | c.6337G>T p.A2113S | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV53263271; called by muse, mutect2, varscan2
- SHANK1 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs928509883, COSV53264876; called by muse, mutect2, varscan2
- SIGLEC9 | c.959G>T p.C320F | Missense Mutation (SNP) | VAF 85/169 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51587350; called by muse, mutect2, varscan2
- SLC15A2 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs760429670, COSV55199321; called by muse, mutect2, varscan2
- SLC6A4 | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs190758123, COSV55565955; called by muse, mutect2, varscan2
- SLC9A9 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1200091128; called by muse, varscan2
- SMARCD1 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56549394; called by muse, mutect2, varscan2
- SPATA31D1 | c.3742G>C p.D1248H | Missense Mutation (SNP) | VAF 119/196 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.172); catalogued as COSV100782469, COSV61195726; called by muse, mutect2, varscan2
- SPEF2 | c.4060G>T p.A1354S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.368); catalogued as rs1162729905; called by muse, mutect2, varscan2
- STARD8 | c.2657T>A p.L886H | Missense Mutation (SNP) | VAF 90/229 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as rs1423953081; called by muse, mutect2, varscan2
- STT3B | c.433G>T p.G145W | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99854263; called by muse, varscan2
- SULT2B1 | c.294G>A p.W98* (on ENST00000201586 / NM_177973.2; = p.W83* on NM_004605.2) | Nonsense Mutation (SNP) | VAF 41/188 reads (22%) | catalogued as COSV52375673; called by muse, mutect2, varscan2
- SVEP1 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 128/191 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs901649784; called by muse, mutect2, varscan2
- SYTL4 | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 83/317 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV52167083, COSV52170524; called by muse, mutect2, varscan2
- TCTE1 | c.615G>T p.Q205H | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1418349380; called by muse, mutect2, varscan2
- TMEM132C | c.490G>T p.G164W | Missense Mutation (SNP) | VAF 263/427 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV70674070; called by muse, mutect2
- TMTC4 | c.1351T>C p.F451L (on ENST00000376234 / NM_001350577.2; = p.F470L on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs539832278; called by muse, mutect2, varscan2
- TSEN2 | c.431A>G p.N144S | Missense Mutation (SNP) | VAF 111/355 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs778603443; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFHX4 | c.9142G>C p.D3048H | Missense Mutation (SNP) | VAF 103/161 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370995988, COSV50584415, COSV50621902; called by muse, mutect2, varscan2
- ZFP42 | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV58816403; called by muse, mutect2, varscan2
- ZNF169 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 118/197 reads (60%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs200550757, COSV61762980; called by muse, mutect2, varscan2
- ZWILCH | c.575G>T p.R192I | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs562042882, COSV57178197; called by muse, mutect2, varscan2
- ACO1 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ACTRT2 | c.965T>A p.L322Q | Missense Mutation (SNP) | VAF 161/282 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ADAM7 | c.884G>T p.W295L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.700C>A p.H234N | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ADGRG7 | c.1147T>A p.C383S | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGPAT1 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 39/474 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- AKAP11 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALPI | c.1436A>T p.H479L | Missense Mutation (SNP) | VAF 126/296 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ANKRD30B | c.80C>A p.T27N | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ANO5 | c.363+1G>T p.X121_splice | Splice Site (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- ARID1A | c.2402dup p.Q802Sfs*15 | Frame Shift Ins (INS) | VAF 61/126 reads (48%) | called by mutect2, pindel, varscan2
- ARID2 | c.5153del p.P1718Qfs*3 | Frame Shift Del (DEL) | VAF 46/85 reads (54%) | called by mutect2, pindel, varscan2
- ASIC2 | c.824A>T p.Q275L | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ASNS | c.1012A>G p.T338A | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ASS1 | c.620A>T p.Y207F | Missense Mutation (SNP) | VAF 233/329 reads (71%) | SIFT tolerated (0.43); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- ATP1A2 | c.2661G>A p.W887* | Nonsense Mutation (SNP) | VAF 272/503 reads (54%) | called by muse, mutect2, varscan2
- AZIN2 | c.1245-6C>T | Splice Region (SNP) | VAF 177/275 reads (64%) | called by muse, mutect2, varscan2
- BEX2 | c.201G>A p.W67* | Nonsense Mutation (SNP) | VAF 67/263 reads (25%) | called by muse, mutect2, varscan2
- BGN | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BIN2 | c.220A>T p.M74L | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- BOD1L1 | c.9127G>T p.E3043* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- BRCA2 | c.6712G>T p.D2238Y | Missense Mutation (SNP) | VAF 98/193 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- BRINP2 | c.10C>A p.Q4K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BTG2 | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 122/246 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C18orf32 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); called by muse, varscan2
- C20orf204 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- CACNA1I | c.524C>A p.S175* | Nonsense Mutation (SNP) | VAF 96/258 reads (37%) | called by muse, mutect2, varscan2
- CACNG8 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CADPS | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC57 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 122/235 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CCM2L | c.1147G>A p.D383N (on ENST00000452892 / NM_001365692.1; = p.R361= on NM_080625.4) | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CDK14 | c.998C>G p.P333R (on ENST00000380050 / NM_001287135.2; = p.P315R on NM_012395.3) | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CEP126 | c.1090G>T p.A364S | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- CEP170 | c.3706G>C p.D1236H | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- CEP63 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 121/397 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- COL24A1 | c.1090A>T p.K364* | Nonsense Mutation (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- COL4A5 | c.1486C>A p.P496T | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- CPNE5 | c.528+1G>C p.X176_splice | Splice Site (SNP) | VAF 284/434 reads (65%) | called by muse, mutect2, varscan2
- CSMD1 | c.8097_8098del p.Y2699* (on ENST00000520002; = p.Y2698* on NM_033225.6) | Nonsense Mutation (DEL) | VAF 49/141 reads (35%) | called by mutect2, pindel, varscan2
- CSMD2 | c.4393del p.Y1465Tfs*11 | Frame Shift Del (DEL) | VAF 144/267 reads (54%) | called by mutect2, pindel, varscan2
- CTDP1 | c.2161G>T p.V721L | Missense Mutation (SNP) | VAF 122/327 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CXCR4 | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 261/731 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CXorf21 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CYP4F3 | c.344C>A p.A115D | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- DCDC1 | c.4893G>T p.E1631D (on ENST00000597505 / NM_001367979.1; = p.E738D on NM_020869.3) | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, varscan2
- DCSTAMP | c.1241G>T p.R414M | Missense Mutation (SNP) | VAF 97/186 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DEFB110 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 90/124 reads (73%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAI2 | c.1726C>A p.Q576K | Missense Mutation (SNP) | VAF 50/456 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC17 | c.821del p.E274Gfs*5 | Frame Shift Del (DEL) | VAF 13/72 reads (18%) | called by mutect2, pindel, varscan2
- DOCK11 | c.74C>A p.S25Y | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- DOT1L | c.761A>G p.K254R | Missense Mutation (SNP) | VAF 81/124 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DSEL | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EIF1B | c.7A>T p.T3S | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIPR1 | c.392del p.N131Tfs*55 | Frame Shift Del (DEL) | VAF 67/185 reads (36%) | called by mutect2, pindel, varscan2
- EMILIN3 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- EN2 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 82/446 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- ENAM | c.3414A>T p.L1138F | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- FAM170A | c.578A>T p.E193V | Missense Mutation (SNP) | VAF 87/163 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FAM193A | c.2077C>T p.H693Y | Missense Mutation (SNP) | VAF 211/506 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FCER2 | c.59G>C p.R20P | Missense Mutation (SNP) | VAF 178/296 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FHL2 | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FNBP1L | c.1723G>T p.G575* (on ENST00000271234 / NM_001164473.2; = p.G517* on NM_017737.5) | Nonsense Mutation (SNP) | VAF 7/113 reads (6%) | called by muse, mutect2
- FOXN4 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 254/515 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRAT1 | c.821T>A p.V274D | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.278); called by muse, varscan2
- FRMPD3 | c.2390C>A p.P797H | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- FRMPD4 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- GABRA3 | c.1183A>T p.T395S | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, varscan2
- GBP3 | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 148/240 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GFAP | c.1360G>C p.E454Q (on ENST00000253408 / NM_001363846.2; = p.E414Q on NM_002055.5) | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- GNAS | c.1781del p.H594Lfs*96 | Frame Shift Del (DEL) | VAF 563/1563 reads (36%) | called by mutect2, pindel, varscan2
- GOLGA6L2 | c.2264G>T p.G755V | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated, low confidence (0.1); called by muse, varscan2
- GOLGA6L2 | c.1811G>T p.G604V | Missense Mutation (SNP) | VAF 104/696 reads (15%) | SIFT tolerated, low confidence (0.08); called by muse, mutect2, varscan2
- GP2 | c.1299G>C p.E433D (on ENST00000381362 / NM_001007240.3; = p.E430D on NM_001502.4) | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- GPR156 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 91/263 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GPRASP1 | c.2820G>A p.W940* | Nonsense Mutation (SNP) | VAF 93/382 reads (24%) | called by muse, mutect2, varscan2
- HCAR1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HDHD5 | c.517G>T p.E173* (on ENST00000336737 / NM_033070.3; = p.E143* on NM_017829.5) | Nonsense Mutation (SNP) | VAF 162/469 reads (35%) | called by muse, mutect2, varscan2
- HGF | c.1443C>G p.D481E | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- HRNR | c.8424T>A p.D2808E | Missense Mutation (SNP) | VAF 191/503 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ICE1 | c.2881C>A p.P961T | Missense Mutation (SNP) | VAF 90/263 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- IPO7 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2
- IRF2BP2 | c.578A>T p.N193I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ITGAX | c.3457G>C p.G1153R | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITIH6 | c.369-1G>T p.X123_splice | Splice Site (SNP) | VAF 47/116 reads (41%) | called by muse, varscan2
- KALRN | c.4138C>A p.P1380T | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF4A | c.2670G>C p.Q890H | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- KLHDC7A | c.1398dup p.R467Afs*32 | Frame Shift Ins (INS) | VAF 140/314 reads (45%) | called by mutect2, pindel, varscan2
- KNSTRN | c.89G>T p.S30I | Missense Mutation (SNP) | VAF 98/203 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- LAMA2 | c.2297G>T p.C766F | Missense Mutation (SNP) | VAF 78/132 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LAMB4 | c.1582C>G p.R528G | Missense Mutation (SNP) | VAF 29/316 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.794); called by muse, mutect2
- LHX1 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 112/464 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- LNPK | c.334T>G p.L112V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LRP1B | c.7881C>A p.N2627K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0.081); called by muse, varscan2
- LRP1B | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- LTBP2 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 194/389 reads (50%) | called by muse, mutect2, varscan2
- MACO1 | c.1258G>A p.G420R | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- MAGEA8 | c.116C>G p.A39G | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- MAN1A2 | c.1025A>T p.E342V | Missense Mutation (SNP) | VAF 60/223 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARCO | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MC2R | c.628C>A p.L210I | Missense Mutation (SNP) | VAF 183/328 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- MIGA1 | c.151A>G p.R51G | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- MUC17 | c.7192C>G p.P2398A | Missense Mutation (SNP) | VAF 179/376 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- MUC3A | c.8574C>A p.N2858K | Missense Mutation (SNP) | VAF 140/474 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- MYH13 | c.535G>C p.G179R | Missense Mutation (SNP) | VAF 186/274 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYO18B | c.1085A>T p.Q362L | Missense Mutation (SNP) | VAF 105/269 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- NDUFS1 | c.616G>T p.V206F | Missense Mutation (SNP) | VAF 132/352 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- NEUROD1 | c.321C>A p.N107K | Missense Mutation (SNP) | VAF 225/528 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NHSL2 | c.347C>A p.S116* (on ENST00000510661; = p.S482* on NM_001013627.2) | Nonsense Mutation (SNP) | VAF 67/168 reads (40%) | called by muse, mutect2, varscan2
- NLGN4X | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- NOVA1 | c.785T>G p.V262G | Missense Mutation (SNP) | VAF 58/514 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- NPR3 | c.32G>T p.W11L | Missense Mutation (SNP) | VAF 99/324 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR3C2 | c.2849A>C p.H950P | Missense Mutation (SNP) | VAF 154/273 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- NRK | c.2669G>T p.W890L | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NWD1 | c.2471C>A p.P824Q | Missense Mutation (SNP) | VAF 132/281 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- ODF3L1 | c.730C>A p.Q244K | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- OLFM1 | c.978G>C p.K326N (on ENST00000371793 / NM_001282611.2; = p.K308N on NM_014279.5) | Missense Mutation (SNP) | VAF 35/334 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.089); called by muse, mutect2
- OR10K2 | c.611C>A p.T204K | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- OR10Z1 | c.505T>A p.C169S | Missense Mutation (SNP) | VAF 64/263 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OR10Z1 | c.593G>T p.R198M | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, varscan2
- OR13C4 | c.939G>T p.R313S | Missense Mutation (SNP) | VAF 46/65 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR1K1 | c.919A>C p.I307L | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2
- OR2A1 | c.295C>A p.Q99K | Missense Mutation (SNP) | VAF 557/1773 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- OR2H2 | c.284G>C p.C95S | Missense Mutation (SNP) | VAF 19/393 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR51B4 | c.633C>G p.I211M | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- OTOG | c.4146C>A p.Y1382* | Nonsense Mutation (SNP) | VAF 53/93 reads (57%) | called by muse, mutect2, varscan2
- OTOGL | c.1210C>G p.P404A (on ENST00000547103; = p.P395A on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- OTUD7A | c.893G>T p.G298V (on ENST00000307050 / NM_001382637.1; = p.G291V on NM_130901.3) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P2RY4 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- PASD1 | c.1607G>A p.R536K | Missense Mutation (SNP) | VAF 50/304 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); called by muse, mutect2
- PCDH11X | c.2805G>C p.L935F | Missense Mutation (SNP) | VAF 163/545 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEG10 | c.620A>T p.H207L (on ENST00000482108 / NM_001040152.2; = p.H241L on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 211/436 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHF6 | c.456G>T p.E152D (on ENST00000332070 / NM_032458.3; = p.E153D on NM_032335.3) | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLCB1 | c.1471A>T p.S491C | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- PLEC | c.13116G>T p.M4372I (on ENST00000322810 / NM_201380.4; = p.M4262I on NM_000445.5) | Missense Mutation (SNP) | VAF 75/124 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- PLEKHG4B | c.2069C>A p.A690E (on ENST00000283426; = p.A1046E on NM_052909.5) | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PMEL | c.1772C>A p.A591E | Missense Mutation (SNP) | VAF 50/460 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- POMK | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PON3 | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POTEJ | c.2389G>T p.V797L | Missense Mutation (SNP) | VAF 154/540 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- PRDX6 | c.41T>G p.F14C | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PROX2 | c.1693T>A p.S565T (on ENST00000556489 / NM_001243007.1; = p.S338T on NM_001080408.2) | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PSG5 | c.551del p.G184Vfs*10 | Frame Shift Del (DEL) | VAF 51/380 reads (13%) | called by mutect2, varscan2
- PYHIN1 | c.1094C>A p.P365H | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- RAB5A | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAD18 | c.110T>A p.I37K | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- RESF1 | c.4139G>A p.G1380E | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- RIMS2 | c.1177A>T p.R393W (on ENST00000666250 / NM_001348490.2; = p.R201W on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTL3 | c.1307G>T p.W436L | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SAMSN1 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- SASH3 | c.755C>A p.P252H | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- SBNO2 | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 116/168 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SFRP2 | c.828G>T p.W276C | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHE | c.790_791insT p.A264Vfs*82 | Frame Shift Ins (INS) | VAF 78/168 reads (46%) | called by mutect2, pindel*, varscan2
- SHROOM2 | c.3322_3323delinsT p.R1108Sfs*32 | Frame Shift Del (DEL) | VAF 33/138 reads (24%) | called by pindel, varscan2*
- SIGLEC10 | c.685A>T p.T229S | Missense Mutation (SNP) | VAF 70/141 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SIGLECL1 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 40/289 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- SORBS2 | c.2329G>A p.A777T | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA31A3 | c.2752C>A p.Q918K | Missense Mutation (SNP) | VAF 70/128 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.132); called by mutect2, varscan2
- SPATA31E1 | c.2885del p.P962Qfs*25 | Frame Shift Del (DEL) | VAF 57/303 reads (19%) | called by mutect2, pindel, varscan2
- SPRY2 | c.853dup p.R285Pfs*3 | Frame Shift Ins (INS) | VAF 121/349 reads (35%) | called by mutect2, pindel, varscan2
- SRPX2 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 133/419 reads (32%) | called by muse, mutect2, varscan2
- SSX3 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 109/368 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- STAC | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- STARD8 | c.1243C>A p.Q415K | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- STXBP1 | c.153G>C p.M51I | Missense Mutation (SNP) | VAF 38/283 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SYNE2 | c.864_872del p.P289_T291del | In Frame Del (DEL) | VAF 64/437 reads (15%) | called by mutect2, pindel, varscan2
- SYNRG | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TENM1 | c.3950G>C p.G1317A | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- TENT4A | c.2053G>T p.V685F | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- TENT4B | c.367_368delinsA p.R123Tfs*117 (on ENST00000561678 / NM_001365323.2; = p.R108Tfs*117 on NM_001040284.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 41/134 reads (31%) | called by pindel, varscan2*
- TGDS | c.149A>G p.D50G | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THAP12 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); called by muse, mutect2
- TIAM1 | c.3316G>T p.V1106L | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2
- TLL2 | c.1364G>A p.G455D | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM222 | c.247A>T p.I83F | Missense Mutation (SNP) | VAF 107/170 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TNFRSF21 | c.1064T>C p.V355A | Missense Mutation (SNP) | VAF 76/736 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRAF3IP2 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.617); called by muse, mutect2
- TRAPPC8 | c.3433G>T p.D1145Y | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, varscan2
- TRIM26 | c.1022A>T p.Y341F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.725); called by muse, varscan2
- TRIM51GP | c.128G>T p.W43L | Missense Mutation (SNP) | VAF 107/211 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- TUBA3C | c.944G>C p.C315S | Missense Mutation (SNP) | VAF 130/298 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- UBE2Q1 | c.1237G>T p.G413C | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UHRF1BP1L | c.3559G>C p.D1187H | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- ULK1 | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- URGCP | c.2294G>C p.G765A (on ENST00000453200 / NM_001077663.3; = p.G756A on NM_017920.4) | Missense Mutation (SNP) | VAF 162/316 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- USH1C | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 53/468 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- VCAN | c.1684C>G p.L562V | Missense Mutation (SNP) | VAF 12/388 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- VN1R4 | c.287G>C p.G96A | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- VSIG4 | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWC2 | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNK4 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- XRCC6 | c.1443dup p.V482Rfs*31 | Frame Shift Ins (INS) | VAF 109/457 reads (24%) | called by mutect2, pindel, varscan2
- ZBBX | c.1194+1G>T p.X398_splice | Splice Site (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- ZEB2 | c.3154G>T p.E1052* | Nonsense Mutation (SNP) | VAF 314/868 reads (36%) | called by muse, mutect2, varscan2
- ZFHX3 | c.1605_1607dup p.L535_M536insI | In Frame Ins (INS) | VAF 38/246 reads (15%) | called by mutect2, pindel, varscan2
- ZNF141 | c.779G>A p.C260Y | Missense Mutation (SNP) | VAF 31/334 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF157 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 76/209 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF423 | c.2501T>A p.L834Q (on ENST00000563137 / NM_001379286.1; = p.L826Q on NM_015069.4) | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF429 | c.670G>T p.V224F | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF536 | c.2012G>T p.R671L | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF563 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 56/311 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF597 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF676 | c.112A>G p.R38G (on ENST00000650058; = p.R6G on NM_001001411.3) | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- ZNF695 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.03); called by muse, varscan2
- ZNF726 | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 105/228 reads (46%) | called by muse, mutect2, varscan2
- ABCC2 | c.249G>T p.L83= | Silent (SNP) | VAF 47/302 reads (16%) | called by muse, varscan2
- ABCC8 | c.4713C>T p.S1571= | Silent (SNP) | VAF 95/815 reads (12%) | catalogued as rs747402972; called by muse, mutect2, varscan2
- ABCF1 | c.1281A>C p.A427= (on ENST00000326195 / NM_001025091.2; = p.A389= on NM_001090.3) | Silent (SNP) | VAF 334/506 reads (66%) | called by muse, mutect2, varscan2
- ACTB | c.525C>T p.I175= | Silent (SNP) | VAF 327/597 reads (55%) | catalogued as rs1472062607; called by muse, mutect2, varscan2
- AGTR1 | c.258C>T p.V86= | Silent (SNP) | VAF 22/173 reads (13%) | catalogued as rs1332854987, COSV62558118; called by muse, mutect2, varscan2
- AK7 | c.1248C>T p.N416= | Silent (SNP) | VAF 37/143 reads (26%) | catalogued as rs757904723, COSV50869155, COSV50869521; called by muse, mutect2, varscan2
- ANKRD10 | c.717A>T p.P239= | Silent (SNP) | VAF 65/131 reads (50%) | called by muse, mutect2, varscan2
- ANKRD17 | c.3780C>T p.C1260= | Silent (SNP) | VAF 17/156 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP45 | c.2355C>T p.I785= | Silent (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- ATMIN | c.1947T>G p.T649= | Silent (SNP) | VAF 37/143 reads (26%) | called by muse, mutect2, varscan2
- BCL9L | c.2454C>G p.A818= | Silent (SNP) | VAF 31/266 reads (12%) | catalogued as COSV52682689; called by muse, mutect2, varscan2
- BGN | c.255C>A p.P85= | Silent (SNP) | VAF 32/116 reads (28%) | called by muse, mutect2, varscan2
- C3 | c.237C>A p.A79= | Silent (SNP) | VAF 73/386 reads (19%) | called by muse, mutect2, varscan2
- C5orf22 | c.1161G>A p.L387= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as rs759422421; called by muse, mutect2, varscan2
- CACNA1C | c.2928G>A p.V976= | Silent (SNP) | VAF 168/335 reads (50%) | called by muse, mutect2, varscan2
- CCDC57 | c.663G>A p.G221= | Silent (SNP) | VAF 71/284 reads (25%) | catalogued as rs1248243306; called by muse, mutect2, varscan2
- CDK18 | c.93G>C p.T31= | Silent (SNP) | VAF 95/185 reads (51%) | called by muse, mutect2, varscan2
- CLCN3 | c.1293C>A p.V431= | Silent (SNP) | VAF 36/175 reads (21%) | called by muse, mutect2, varscan2
- COPA | c.516G>A p.L172= | Silent (SNP) | VAF 97/243 reads (40%) | called by muse, mutect2, varscan2
- CORIN | c.2998T>C p.L1000= | Silent (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- CYLC1 | c.123C>A p.L41= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100255128; called by muse, mutect2, varscan2
- DIAPH3 | c.1009C>T p.L337= (on ENST00000400324 / NM_001042517.2; = p.L74= on NM_030932.3) | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as rs1341351701; called by muse, mutect2, varscan2
- DSC1 | c.1653A>T p.A551= | Silent (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- ERMARD | c.393G>A p.S131= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs377727194; ClinVar: likely benign; called by muse, mutect2, varscan2
- FARP2 | c.1509G>A p.Q503= | Silent (SNP) | VAF 78/181 reads (43%) | called by muse, mutect2, varscan2
- FAT1 | c.11547C>T p.N3849= | Silent (SNP) | VAF 50/186 reads (27%) | called by muse, mutect2, varscan2
- GIT1 | c.951T>A p.V317= | Silent (SNP) | VAF 102/239 reads (43%) | called by muse, mutect2, varscan2
- GOLGA8S | c.1329G>A p.L443= | Silent (SNP) | VAF 44/232 reads (19%) | called by mutect2, varscan2
- GRM6 | c.1920C>T p.L640= | Silent (SNP) | VAF 142/295 reads (48%) | called by muse, mutect2, varscan2
- GRM8 | c.1959C>T p.V653= | Silent (SNP) | VAF 22/336 reads (7%) | catalogued as COSV58852605, COSV58870765; called by muse, mutect2
- GSE1 | c.1716G>T p.S572= | Silent (SNP) | VAF 26/132 reads (20%) | called by muse, mutect2, varscan2
- GTF3C5 | c.6G>T p.A2= | Silent (SNP) | VAF 138/193 reads (72%) | called by muse, mutect2, varscan2
- H2AC1 | c.129G>C p.R43= | Silent (SNP) | VAF 328/490 reads (67%) | called by muse, mutect2, varscan2
- HMOX1 | c.504C>T p.T168= | Silent (SNP) | VAF 213/727 reads (29%) | catalogued as rs1326695183; called by muse, mutect2, varscan2
- HSFX1 | c.216C>A p.A72= | Silent (SNP) | VAF 22/160 reads (14%) | called by mutect2, varscan2
- IGKV2D-26 | c.91T>C p.L31= | Silent (SNP) | VAF 21/193 reads (11%) | called by muse, mutect2, varscan2
- IGLV3-25 | c.132T>C p.D44= | Silent (SNP) | VAF 264/638 reads (41%) | catalogued as rs374099428; called by muse, mutect2, varscan2
- IQGAP1 | c.4845T>C p.F1615= | Silent (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- KLHL3 | c.552A>G p.L184= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- KRT83 | c.114C>T p.R38= | Silent (SNP) | VAF 98/693 reads (14%) | catalogued as rs558452885, COSV53342439; called by muse, mutect2, varscan2
- KRTAP24-1 | c.84G>T p.V28= | Silent (SNP) | VAF 42/119 reads (35%) | called by muse, mutect2, varscan2
- L3MBTL2 | c.195G>A p.P65= | Silent (SNP) | VAF 142/391 reads (36%) | catalogued as rs144068377; called by muse, mutect2, varscan2
- LAMA2 | c.711C>T p.S237= | Silent (SNP) | VAF 49/83 reads (59%) | catalogued as rs369745832; ClinVar: likely benign; called by muse, mutect2, varscan2
- LCT | c.501G>T p.G167= | Silent (SNP) | VAF 226/615 reads (37%) | called by muse, mutect2, varscan2
- LILRA1 | c.930C>A p.P310= | Silent (SNP) | VAF 15/302 reads (5%) | called by muse, mutect2
- MAGEL2 | c.1113C>A p.T371= | Silent (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- MAS1L | c.330A>T p.V110= | Silent (SNP) | VAF 323/499 reads (65%) | called by muse, mutect2, varscan2
- MC5R | c.387C>T p.S129= | Silent (SNP) | VAF 43/342 reads (13%) | catalogued as rs1007236921; called by muse, mutect2, varscan2
- MPP3 | c.720G>T p.R240= | Silent (SNP) | VAF 112/486 reads (23%) | called by mutect2, varscan2
- MROH1 | c.111G>A p.E37= | Silent (SNP) | VAF 23/197 reads (12%) | catalogued as rs752695630; called by muse, mutect2, varscan2
- MUL1 | c.966C>T p.S322= | Silent (SNP) | VAF 17/140 reads (12%) | catalogued as rs1422503829; called by muse, mutect2, varscan2
- OR56A5 | c.105C>T p.S35= | Silent (SNP) | VAF 38/200 reads (19%) | called by muse, mutect2, varscan2
- OR5L1 | c.405C>A p.T135= | Silent (SNP) | VAF 36/187 reads (19%) | catalogued as COSV61732757; called by muse, mutect2, varscan2
- OR6P1 | c.60G>A p.T20= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs937643591, COSV58109851; called by muse, mutect2, varscan2
- OR6T1 | c.600C>T p.F200= | Silent (SNP) | VAF 44/478 reads (9%) | catalogued as COSV58308219; called by muse, mutect2
- PCDHB4 | c.226C>T p.L76= | Silent (SNP) | VAF 29/165 reads (18%) | called by muse, mutect2, varscan2
- PHLPP2 | c.1749G>T p.T583= | Silent (SNP) | VAF 19/103 reads (18%) | called by muse, mutect2, varscan2
- PKP2 | c.2130G>T p.T710= | Silent (SNP) | VAF 227/517 reads (44%) | catalogued as rs371089832, COSV50726459; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLEKHO1 | c.345G>T p.V115= | Silent (SNP) | VAF 113/239 reads (47%) | called by muse, mutect2, varscan2
- PLXNA4 | c.762C>G p.V254= | Silent (SNP) | VAF 157/293 reads (54%) | called by muse, mutect2, varscan2
- PLXNB3 | c.3024C>A p.P1008= | Silent (SNP) | VAF 57/189 reads (30%) | called by muse, mutect2, varscan2
- PNPLA1 | c.1488C>T p.D496= (on ENST00000394571 / NM_001374623.1; = p.D401= on NM_173676.2) | Silent (SNP) | VAF 159/218 reads (73%) | catalogued as rs910041180; called by muse, mutect2, varscan2
- PRPS1L1 | c.249C>T p.S83= | Silent (SNP) | VAF 195/820 reads (24%) | called by muse, mutect2, varscan2
- PRSS1 | c.237A>G p.E79= | Silent (SNP) | VAF 58/1412 reads (4%) | catalogued as COSV61190610; called by muse, mutect2
- RAB11FIP1 | c.309C>T p.F103= | Silent (SNP) | VAF 31/219 reads (14%) | catalogued as COSV54763443; called by muse, mutect2, varscan2
- RELN | c.9573C>T p.I3191= | Silent (SNP) | VAF 439/795 reads (55%) | called by muse, mutect2, varscan2
- RGS12 | c.213C>T p.N71= | Silent (SNP) | VAF 21/180 reads (12%) | catalogued as rs139673399; called by muse, mutect2, varscan2
- SASH3 | c.756C>A p.P252= | Silent (SNP) | VAF 18/124 reads (15%) | called by muse, varscan2
- SCUBE1 | c.1629G>A p.K543= | Silent (SNP) | VAF 52/170 reads (31%) | called by muse, mutect2, varscan2
- SENP7 | c.72A>G p.S24= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as rs762201367; called by muse, mutect2, varscan2
- SETD1B | c.2592C>A p.V864= | Silent (SNP) | VAF 169/286 reads (59%) | called by muse, mutect2, varscan2
- SHANK1 | c.1338C>A p.P446= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as rs555577816; called by muse, mutect2, varscan2
- SHISA7 | c.513G>C p.G171= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs764184885; called by muse, mutect2, varscan2
- SIK3 | c.162C>T p.P54= (on ENST00000445177 / NM_001366686.2; = p.P60= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 164/270 reads (61%) | catalogued as rs1425878718; called by muse, mutect2, varscan2
- SLC9A4 | c.333C>A p.G111= | Silent (SNP) | VAF 120/335 reads (36%) | catalogued as rs375903377, COSV54834628; called by muse, mutect2
- STAC | c.588G>T p.V196= | Silent (SNP) | VAF 26/73 reads (36%) | called by muse, mutect2, varscan2
- TDRD1 | c.3039G>A p.L1013= | Silent (SNP) | VAF 22/154 reads (14%) | called by muse, mutect2, varscan2
- TEX15 | c.3591T>C p.S1197= (on ENST00000256246; = p.S1580= on NM_001350162.2) | Silent (SNP) | VAF 105/174 reads (60%) | called by muse, mutect2, varscan2
- THOC1 | c.111C>T p.F37= | Silent (SNP) | VAF 53/99 reads (54%) | called by muse, mutect2, varscan2
- THPO | c.780C>T p.L260= (on ENST00000649095 / NM_001290003.1; = p.L120= on NM_000460.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 78/218 reads (36%) | catalogued as rs375553609; called by muse, mutect2, varscan2
- TIAM1 | c.3318G>T p.V1106= | Silent (SNP) | VAF 28/121 reads (23%) | called by muse, mutect2
- TIMD4 | c.960C>A p.A320= | Silent (SNP) | VAF 40/76 reads (53%) | catalogued as rs750922432; called by muse, mutect2, varscan2
- TJAP1 | c.1023C>T p.I341= (on ENST00000372445 / NM_001146016.1; = p.I331= on NM_080604.3) | Silent (SNP) | VAF 21/422 reads (5%) | called by muse, mutect2
- TOPAZ1 | c.4329G>C p.T1443= | Silent (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- URGCP | c.2295G>T p.G765= (on ENST00000453200 / NM_001077663.3; = p.G756= on NM_017920.4) | Silent (SNP) | VAF 167/325 reads (51%) | called by muse, mutect2, varscan2
- VPS13C | c.6636G>C p.V2212= (on ENST00000644861 / NM_020821.3; = p.V2169= on NM_017684.5) | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs778103115, COSV51195807; called by muse, varscan2
- VPS13D | c.1482T>C p.H494= | Silent (SNP) | VAF 69/132 reads (52%) | catalogued as rs1179727685; called by muse, mutect2, varscan2
- XDH | c.2604G>T p.V868= | Silent (SNP) | VAF 156/403 reads (39%) | called by muse, mutect2, varscan2
- ZEB2 | c.642C>T p.P214= | Silent (SNP) | VAF 181/480 reads (38%) | called by muse, varscan2
- ZNF182 | c.1101C>A p.T367= | Silent (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- ZNF546 | c.1929G>A p.G643= | Silent (SNP) | VAF 111/217 reads (51%) | catalogued as rs563297844; called by muse, mutect2, varscan2
- ZNF738 | c.102G>A p.P34= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs750021088, COSV60616305; called by muse, mutect2, varscan2
- ZNF850 | c.1029A>G p.G343= | Silent (SNP) | VAF 12/263 reads (5%) | called by muse, mutect2
- AC018638.4 | n.1011G>T | RNA (SNP) | VAF 316/1458 reads (22%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847244 G>A | 5'Flank (SNP) | VAF 55/238 reads (23%) | catalogued as rs924862561; called by muse, mutect2, varscan2
- AL603840.1 | n.736C>A | RNA (SNP) | VAF 21/35 reads (60%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.2176+95G>T | Intron (SNP) | VAF 33/103 reads (32%) | catalogued as COSV57301115; called by muse, mutect2, varscan2
- ARHGAP6 | c.1908-4476C>T | Intron (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+1619T>A | Intron (SNP) | VAF 126/420 reads (30%) | called by muse, mutect2, varscan2
- ATRX | c.6850-23G>T | Intron (SNP) | VAF 58/176 reads (33%) | called by muse, varscan2
- CCDC116 | c.1203+140A>G | Intron (SNP) | VAF 133/329 reads (40%) | called by muse, mutect2, varscan2
- CD5L | c.*8G>C | 3'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- CDKL1 | c.171+17476C>A | Intron (SNP) | VAF 61/257 reads (24%) | called by muse, mutect2, varscan2
- COL7A1 | c.7069-50C>G | Intron (SNP) | VAF 111/328 reads (34%) | called by muse, mutect2, varscan2
- DCHS2 | n.847G>A | RNA (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- DENND5B | c.128-4515G>T | Intron (SNP) | VAF 110/217 reads (51%) | called by muse, mutect2, varscan2
- DNAI4 | c.940+12C>G | Intron (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- DYNLRB2 | chr16:80540807 C>T | 5'Flank (SNP) | VAF 93/255 reads (36%) | catalogued as rs75009985; called by muse, mutect2, varscan2
- ERVV-1 | chr19:53010070 G>A | 5'Flank (SNP) | VAF 24/183 reads (13%) | called by muse, mutect2, varscan2
- G6PD | chrX:154531994 C>A | 3'Flank (SNP) | VAF 84/267 reads (31%) | called by muse, mutect2, varscan2
- GMPPA | c.854-36G>T | Intron (SNP) | VAF 52/143 reads (36%) | called by muse, mutect2, varscan2
- GZMB | c.55+133G>T | Intron (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- HNRNPLL | c.-196C>G | 5'UTR (SNP) | VAF 23/229 reads (10%) | catalogued as rs778620766; called by muse, mutect2
- IAH1 | c.81+554C>A | Intron (SNP) | VAF 51/161 reads (32%) | called by muse, mutect2, varscan2
- ITIH5 | c.939+6526C>A | Intron (SNP) | VAF 62/201 reads (31%) | called by muse, mutect2, varscan2
- KREMEN1 | c.*8C>T | 3'UTR (SNP) | VAF 78/201 reads (39%) | called by muse, mutect2, varscan2
- LINC01561 | n.491G>T | RNA (SNP) | VAF 19/30 reads (63%) | called by muse, mutect2, varscan2
- MAPK11 | c.448-19C>T | Intron (SNP) | VAF 21/246 reads (9%) | catalogued as rs761644943; called by muse, mutect2
- MITF | c.-2C>T | 5'UTR (SNP) | VAF 55/154 reads (36%) | called by muse, mutect2, varscan2
- MRRFP1 | n.484G>T | RNA (SNP) | VAF 49/183 reads (27%) | called by muse, mutect2, varscan2
- NTM-AS1 | n.1787T>A | RNA (SNP) | VAF 108/227 reads (48%) | catalogued as rs1265898288; called by muse, mutect2, varscan2
- OR52A4P | chr11:5121154 C>T | 3'Flank (SNP) | VAF 9/84 reads (11%) | catalogued as rs202077616; called by muse, mutect2, varscan2
- OR5H15 | c.926-34C>A | Intron (SNP) | VAF 25/86 reads (29%) | catalogued as rs530251764; called by muse, mutect2, varscan2
- PTPRQ | c.19+1200C>A | Intron (SNP) | VAF 58/140 reads (41%) | called by muse, mutect2, varscan2
- SDC4 | c.-9C>G | 5'UTR (SNP) | VAF 66/185 reads (36%) | catalogued as rs760647418, COSV65595545; called by muse, mutect2, varscan2
- SH3GL3 | c.-16G>T | 5'UTR (SNP) | VAF 30/89 reads (34%) | called by muse, mutect2, varscan2
- SIGLEC17P | n.268G>T | RNA (SNP) | VAF 90/173 reads (52%) | called by muse, mutect2, varscan2
- ST20-MTHFS | c.-169C>G | 5'UTR (SNP) | VAF 18/104 reads (17%) | called by muse, mutect2, varscan2
- TAF1 | c.5336+125G>C | Intron (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- TBL1X | c.*23G>T | 3'UTR (SNP) | VAF 35/123 reads (28%) | catalogued as rs761388448; called by muse, mutect2, varscan2
- TOM1L1 | c.720+48A>G | Intron (SNP) | VAF 38/73 reads (52%) | called by muse, mutect2, varscan2
- TPP2 | c.-31T>G | 5'UTR (SNP) | VAF 69/165 reads (42%) | called by muse, mutect2, varscan2
- UBE2DNL | n.557C>A | RNA (SNP) | VAF 23/160 reads (14%) | called by muse, mutect2, varscan2
- XIAP | c.*1220G>T | 3'UTR (SNP) | VAF 46/155 reads (30%) | called by muse, mutect2, varscan2
- ZIC4 | c.688+1926G>T | Intron (SNP) | VAF 49/165 reads (30%) | catalogued as rs1483910912; called by muse, mutect2
- ZNF264 | c.-1G>A | 5'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- ZNF721 | c.-3+26471G>C | Intron (SNP) | VAF 63/145 reads (43%) | called by muse, mutect2, varscan2
- ZNF849P | n.917G>T | RNA (SNP) | VAF 66/373 reads (18%) | called by muse, mutect2, varscan2
